Somatic mutation profile of tumor specimen TCGA-G4-6317-02A (aliquot TCGA-G4-6317-02A-11D-2067-10) from TCGA case TCGA-G4-6317, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.5 years (18,822 days).
Specimen TCGA-G4-6317-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7625971a-3751-4b43-b3be-1cb915ebc27d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6317-10A (Blood Derived Normal), aliquot TCGA-G4-6317-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3bb2711-cffa-4cc6-b4cc-5c0a8f31a0c4

The open-access MAF lists 142 somatic variants for this specimen: 108 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 31, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, 3'UTR 2, Intron 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as rs758892087, COSV100717447, COSV100717452; called by muse, mutect2, varscan2
- ACOX2 | c.1201T>A p.C401S | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100250068; called by muse, mutect2
- ADCY5 | c.2577G>T p.R859S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100567456; called by muse, mutect2, varscan2
- ADGRL3 | c.2114C>A p.A705E (on ENST00000506720 / NM_001322402.2; = p.A637E on NM_015236.6) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV72230225; called by muse, mutect2, varscan2
- ADSS1 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1054399252, COSV100272168; called by muse, mutect2, varscan2
- AMOTL1 | c.178A>T p.S60C | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV100133681; called by muse, mutect2, varscan2
- ANKRD13A | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1012068764, COSV55676025; called by muse, mutect2, varscan2
- ARID5A | c.1188_1196del p.S397_F399del | In Frame Del (DEL) | VAF 37/108 reads (34%) | catalogued as COSV62590941; called by mutect2, pindel, varscan2
- AWAT1 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100997185; called by muse, mutect2
- B4GALT5 | c.1073A>T p.N358I | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100866952; called by muse, mutect2
- BCKDHB | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1354121882, CD126902, COSV57511732; called by muse, mutect2
- BCORL1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs749559990, COSV54401328; called by muse, mutect2, varscan2
- BICRA | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.104); catalogued as COSV101194255; called by muse, mutect2, varscan2
- BSX | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV58006623; called by muse, mutect2, varscan2
- C9orf40 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.341); catalogued as COSV100964958; called by muse, mutect2
- CABS1 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV56734186, COSV56734591; called by muse, mutect2, varscan2
- CCDC58 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV99360432; called by muse, mutect2, varscan2
- CDH8 | c.2114A>C p.Q705P | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.803); catalogued as COSV100180359; called by muse, mutect2, varscan2
- CELSR1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53098458, COSV99416884; called by muse, mutect2, varscan2
- CIR1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.824); catalogued as COSV100564915; called by muse, mutect2, varscan2
- CNBD1 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73073066; called by muse, mutect2, varscan2
- CNGB3 | c.1282T>A p.F428I | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100181532; called by muse, mutect2, varscan2
- CNNM1 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63202616; called by muse, mutect2
- CNTNAP5 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs751028037, COSV70476456; called by mutect2, varscan2
- COL24A1 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65308203; called by muse, mutect2, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 46/175 reads (26%) | catalogued as rs1385226543; called by mutect2, varscan2
- CYP46A1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952335; called by muse, mutect2, varscan2
- CYP4A22 | c.994T>A p.W332R | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594705; called by muse, varscan2
- CYP4A22 | c.995G>A p.W332* | Nonsense Mutation (SNP) | VAF 41/350 reads (12%) | catalogued as COSV53739586; called by muse, mutect2, varscan2
- DHX34 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV60895095; called by muse, mutect2, varscan2
- DNMT3B | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs774138031, COSV99140659; called by muse, mutect2, varscan2
- DPY19L2 | c.1863A>T p.E621D | Missense Mutation (SNP) | VAF 97/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193031; called by muse, mutect2, varscan2
- DSP | c.4254G>C p.Q1418H | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV101131201; called by muse, mutect2, varscan2
- EFNB2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as rs763200557, COSV55364897, COSV55366729; called by muse, mutect2
- EFR3A | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV99602648; called by muse, mutect2
- EPHA3 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752560194, COSV60705886; called by muse, mutect2, varscan2
- ERBB2 | c.2521C>G p.L841V | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54063600; called by muse, mutect2, varscan2
- F5 | c.2707G>A p.G903R | Missense Mutation (SNP) | VAF 143/224 reads (64%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs768379997, COSV63122080; called by muse, varscan2
- F8 | c.986G>C p.C329S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM010846, CM071732, CM073056, COSV100811386; called by muse, mutect2, varscan2
- FBXO10 | c.1860C>A p.C620* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV99446393; called by muse, mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 54/118 reads (46%) | catalogued as rs766041577; called by mutect2, varscan2
- FRK | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as rs144021686; called by muse, mutect2, varscan2
- GPRC6A | c.947A>C p.N316T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100114176, COSV59954288; called by muse, mutect2, varscan2
- GRIA4 | c.1631C>A p.A544D | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99229905; called by muse, mutect2
- GZMA | c.787T>A p.*263Kext*? | Nonstop Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99696664; called by muse, mutect2, varscan2
- HUWE1 | c.7913C>T p.A2638V | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99471221; called by muse, mutect2, varscan2
- ITPKA | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV99540690; called by muse, mutect2, varscan2
- ITPR3 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65410522, COSV65411208; called by muse, mutect2, varscan2
- IVNS1ABP | c.532-1G>C p.X178_splice | Splice Site (SNP) | VAF 33/106 reads (31%) | catalogued as rs1025693888, COSV100832509, COSV100832543; called by muse, mutect2, varscan2
- KLF6 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99434958; called by muse, mutect2, varscan2
- KMO | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99053221; called by muse, mutect2, varscan2
- LAMA2 | c.2753G>T p.C918F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370249; called by muse, mutect2, varscan2
- LDHB | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100636390; called by muse, mutect2, varscan2
- LONRF2 | c.1769A>G p.Y590C | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101110890; called by muse, mutect2, varscan2
- LONRF3 | c.2155T>A p.W719R (on ENST00000371628 / NM_001031855.3; = p.W678R on NM_024778.5) | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100504298; called by muse, mutect2, varscan2
- LRRC39 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 45/110 reads (41%) | catalogued as rs371155598; called by muse, mutect2, varscan2
- MAPKAP1 | c.670A>G p.N224D | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV99784551; called by muse, mutect2, varscan2
- METTL7B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1294128445, COSV99144851; called by muse, mutect2, varscan2
- MMP16 | c.1439G>T p.W480L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686839; called by muse, mutect2
- MON1B | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99941604; called by muse, mutect2, varscan2
- MYO9B | c.1033G>T p.V345F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101261424; called by muse, mutect2, varscan2
- NALCN | c.5075G>T p.G1692V | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.193); catalogued as COSV99213749; called by muse, mutect2
- NLRP2 | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.772); catalogued as COSV99672028; called by muse, mutect2, varscan2
- OR6C6 | c.852T>A p.N284K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs961166651, COSV64455694, COSV64455899; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2, varscan2
- OSCAR | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99499874; called by muse, mutect2
- PIK3R4 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768302; called by muse, mutect2, varscan2
- PLIN4 | c.2180C>T p.A727V (on ENST00000301286; = p.A742V on NM_001367868.2) | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202029971, COSV56687242; called by muse, varscan2
- PSMD6 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs376956971, COSV99895933; called by muse, mutect2, varscan2
- RNF148 | c.416T>A p.V139E | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100411513; called by muse, mutect2, varscan2
- RPP21 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935672; called by muse, mutect2, varscan2
- SCRN2 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 78/84 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV99274002; called by muse, mutect2, varscan2
- SEC13 | c.127C>T p.R43C (on ENST00000350697 / NM_183352.3; = p.R46C on NM_030673.4) | Missense Mutation (SNP) | VAF 158/305 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs757416423, COSV61602010; called by muse, mutect2, varscan2
- SFMBT2 | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100738661; called by muse, mutect2, varscan2
- SLC17A3 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.023); catalogued as rs777792762, COSV100399124; called by muse, mutect2, varscan2
- SLITRK2 | c.1576C>A p.L526M | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100157506; called by muse, mutect2
- STXBP2 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs755227395, COSV99657043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 119/221 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs762377253; called by muse, mutect2, varscan2
- SUSD4 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755571168, COSV59551610; called by muse, mutect2, varscan2
- SYNE1 | c.6361C>A p.L2121I (on ENST00000367255 / NM_182961.4; = p.L2128I on NM_033071.3) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54947519, COSV55000861; called by muse, mutect2, varscan2
- TCF7L2 | c.754C>T p.Q252* (on ENST00000355995 / NM_001367943.1; = p.Q229* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV53339579; called by muse, mutect2, varscan2
- TEX15 | c.5715C>A p.S1905R (on ENST00000256246; = p.S2288R on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99820990; called by muse, mutect2, varscan2
- TMEM41A | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs758579316, COSV99956538; called by muse, mutect2, varscan2
- TMEM74 | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99865525; called by muse, mutect2, varscan2
- TP53 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 140/152 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52680549, COSV52752618; called by muse, mutect2, varscan2
- TPO | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61096505; called by muse, mutect2, varscan2
- TRAM1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51597001, COSV99140738; called by muse, mutect2, varscan2
- TRIO | c.9137A>T p.Q3046L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100702488; called by muse, mutect2, varscan2
- TRPC3 | c.386G>A p.R129H (on ENST00000379645 / NM_001366479.2; = p.R56H on NM_003305.2) | Missense Mutation (SNP) | VAF 84/92 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775346133, COSV53378201; called by muse, mutect2, varscan2
- TUSC3 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 74/80 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101140879; called by muse, mutect2, varscan2
- UNC79 | c.1315G>A p.A439T (on ENST00000393151 / NM_001346218.2; = p.A262T on NM_020818.5) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs199853805, COSV56382871; called by muse, mutect2, varscan2
- VBP1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.499); catalogued as COSV99660765; called by muse, mutect2, varscan2
- WSCD1 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100496463; called by muse, mutect2, varscan2
- WWC3 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1274966173, COSV66509622; called by muse, mutect2, varscan2
- ZC3H13 | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 20/409 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99667716; called by muse, mutect2
- ZMAT4 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.174); catalogued as COSV99909117; called by muse, mutect2, varscan2
- ZNF385C | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as rs368510158; called by muse, mutect2, varscan2
- ZNF688 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99794131; called by muse, mutect2, varscan2
- ZSCAN18 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV99559226; called by muse, mutect2, varscan2
- ZSCAN31 | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60180666; called by muse, mutect2, varscan2
- ZSCAN5B | c.1187C>G p.S396* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV61999683; called by muse, mutect2, varscan2
- APC | c.3846_3854delinsT p.A1283* | Frame Shift Del (DEL) | VAF 99/113 reads (88%) | called by pindel, varscan2*
- GLI3 | c.12dup p.S5Vfs*8 | Frame Shift Ins (INS) | VAF 26/192 reads (14%) | called by mutect2, varscan2
- GLI3 | c.9_10del p.Q4Vfs*8 | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | called by mutect2, pindel*, varscan2
- MARK2 | c.1493_1514+1del p.X498_splice (on ENST00000402010 / NM_001039469.2; = p.X497_splice on NM_004954.5) | Splice Site (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- SAMSN1 | c.719del p.S240Tfs*11 | Frame Shift Del (DEL) | VAF 49/300 reads (16%) | called by mutect2, pindel, varscan2
- SLC22A14 | c.326dup p.H109Qfs*6 | Frame Shift Ins (INS) | VAF 33/207 reads (16%) | called by mutect2, pindel, varscan2
- THOC2 | c.215_222+1dup p.X72_splice | Splice Site (INS) | VAF 20/126 reads (16%) | called by mutect2, varscan2
- ABCC8 | c.4524G>A p.T1508= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as rs553746345, COSV100216870; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSM5 | c.1366C>A p.R456= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV100088615, COSV59370169; called by muse, mutect2, varscan2
- ADAM29 | c.339G>T p.L113= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100821939; called by muse, mutect2, varscan2
- ARHGAP19 | c.267C>T p.G89= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs769370762, COSV57393225; called by muse, mutect2, varscan2
- CACNA1I | c.1095C>T p.Y365= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs57495596, COSV100359653; called by muse, mutect2, varscan2
- DSG3 | c.267A>T p.G89= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs1278062892, COSV99933935; called by muse, mutect2, varscan2
- DUSP3 | c.51G>A p.S17= | Silent (SNP) | VAF 46/49 reads (94%) | catalogued as COSV99871424; called by muse, mutect2, varscan2
- FLG2 | c.5898G>A p.G1966= | Silent (SNP) | VAF 60/235 reads (26%) | catalogued as rs751285860, COSV66166679, COSV66170743; called by muse, mutect2, varscan2
- GABRG2 | c.1461C>A p.I487= (on ENST00000361925 / NM_001375343.1; = p.I447= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/246 reads (63%) | catalogued as COSV100729623; called by muse, mutect2, varscan2
- GPD1L | c.657C>T p.L219= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99245604; called by muse, mutect2
- GZMA | c.786T>A p.V262= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99696661; called by muse, mutect2, varscan2
- HACE1 | c.1639A>C p.R547= | Silent (SNP) | VAF 137/318 reads (43%) | catalogued as COSV99493446; called by muse, mutect2, varscan2
- ITGB7 | c.510C>T p.R170= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99913980; called by muse, mutect2, varscan2
- LRRC4C | c.927A>T p.I309= | Silent (SNP) | VAF 102/219 reads (47%) | catalogued as COSV99537471; called by muse, mutect2, varscan2
- NCS1 | c.249C>T p.S83= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1417102355, COSV64962461; called by muse, mutect2, varscan2
- NLRP2 | c.822A>C p.P274= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99672030; called by muse, mutect2, varscan2
- OR13A1 | c.855C>T p.S285= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs189836358; called by muse, mutect2, varscan2
- OR52I1 | c.642T>C p.D214= | Silent (SNP) | VAF 92/200 reads (46%) | catalogued as COSV100331661; called by muse, mutect2, varscan2
- OR5D18 | c.84C>G p.L28= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as COSV100450592, COSV61736049, COSV61738497; called by muse, mutect2, varscan2
- POU4F3 | c.585G>A p.K195= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100046920; called by muse, mutect2, varscan2
- PSD2 | c.1524G>A p.A508= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs574247018, COSV51201316; called by muse, mutect2, varscan2
- RHAG | c.114C>T p.I38= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as COSV100006451; called by muse, mutect2, varscan2
- SH2D1B | c.150C>G p.V50= | Silent (SNP) | VAF 105/163 reads (64%) | catalogued as COSV100854772, COSV100854835; called by muse, mutect2, varscan2
- SHISAL1 | c.474G>A p.P158= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs368687548; called by muse, mutect2, varscan2
- SLMAP | c.324C>T p.D108= | Silent (SNP) | VAF 131/238 reads (55%) | catalogued as rs541100817, COSV99908238; called by muse, mutect2, varscan2
- SMOX | c.1347G>A p.T449= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs79238665, COSV53865221; called by muse, mutect2, varscan2
- TAF4 | c.2490C>T p.D830= | Silent (SNP) | VAF 57/232 reads (25%) | catalogued as rs1330584594, COSV99433727; called by muse, mutect2, varscan2
- TRIM62 | c.693C>A p.I231= | Silent (SNP) | VAF 64/89 reads (72%) | catalogued as COSV99357706, COSV99357860; called by muse, mutect2, varscan2
- ZBTB7A | c.489C>T p.F163= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100475511, COSV59326938; called by muse, mutect2, varscan2
- ZIC1 | c.408C>T p.D136= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV51550748, COSV51553019; called by muse, mutect2, varscan2
- ZNF462 | c.5649C>T p.N1883= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs750506205, COSV99471174; called by muse, mutect2, varscan2
- ATP2B2 | c.*57G>A | 3'UTR (SNP) | VAF 34/94 reads (36%) | catalogued as rs373130153; called by muse, mutect2, varscan2
- COL3A1 | c.*2_*3del | 3'UTR (DEL) | VAF 31/189 reads (16%) | called by mutect2, pindel, varscan2
- MTHFR | c.-13-355G>T | Intron (SNP) | VAF 52/95 reads (55%) | catalogued as COSV100411703; called by muse, mutect2, varscan2
